Somatic mutation profile of tumor specimen MBCProject_0063_T1_WES (aliquot MBCProject_0063_T1_WES_1) from CMI case MBCProject_0063, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.6 years (15,923 days).
Specimen MBCProject_0063_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18136b8e-1e34-4f71-8a5c-ed9673251f2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0063_SALIVA (Saliva), aliquot MBCProject_0063_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd0cf8f7-53d8-4be9-9eac-95c37f2b2579

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Splice Site 3, Frame Shift Del 2, 3'Flank 1, Splice Region 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 38/60 reads (63%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- KLF4 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 153/410 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV65928521; called by muse, mutect2, varscan2
- ARFGEF3 | c.4387G>A p.A1463T | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1255461168; called by muse, varscan2
- BEND2 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV66217074; called by muse, mutect2, varscan2
- CACNA1H | c.3904G>A p.V1302I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200904795, COSV61990360; called by muse, mutect2, varscan2
- CD276 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV59205903; called by mutect2, varscan2
- ELOF1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs755727195, COSV52948391; called by muse, mutect2, varscan2
- FIP1L1 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1222597263; called by muse, mutect2, varscan2
- IGHM | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.2); catalogued as rs868948115; called by mutect2, varscan2
- MKI67 | c.1450G>T p.V484F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs868566692; called by muse, varscan2
- MTARC1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs866451333, COSV65055695, COSV65056392; called by muse, mutect2, varscan2
- NCKAP5 | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1248199831; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 85/169 reads (50%) | catalogued as rs146650273; called by pindel, varscan2
- RUBCN | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99584877; called by muse, mutect2, varscan2
- SEMA4F | c.556dup p.X186_splice | Splice Site (INS) | VAF 15/66 reads (23%) | catalogued as rs749720924; called by mutect2, varscan2
- SETBP1 | c.4577C>T p.P1526L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1345338635; called by muse, mutect2, varscan2
- SIAH3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs1325336463, COSV68553040; called by muse, mutect2, varscan2
- TBL1XR1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV70501035, COSV99081487; called by muse, mutect2, varscan2
- ZNF618 | c.2719G>A p.A907T (on ENST00000374126 / NM_001318042.2; = p.A814T on NM_133374.2) | Missense Mutation (SNP) | VAF 113/348 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761662307; called by muse, mutect2, varscan2
- ABCC10 | c.4229C>G p.A1410G (on ENST00000372530 / NM_001198934.2; = p.A1382G on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLEC17A | c.1005-11_1005-1delinsTTTTTTTTTTT p.X335_splice (on ENST00000417570 / NM_001204118.2; = p.X299_splice on NM_207390.3) | Splice Site (ONP) | VAF 4/47 reads (9%) | called by mutect2*, pindel
- DDX39A | c.795_802del p.V266Qfs*4 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- DNAH12 | c.5459A>G p.E1820G (on ENST00000351747; = p.E1839G on NM_001366028.2) | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DPM1 | c.523T>G p.L175V | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- EPHB4 | c.1531T>A p.S511T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HSPG2 | c.10150+2T>C p.X3384_splice | Splice Site (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4195T>C p.S1399P (on ENST00000321505; = p.S1696P on NM_012194.3) | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYOF | c.433+4A>C | Splice Region (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- PDCD4 | c.1235T>A p.I412N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC10A4 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEND3 | c.1887C>T p.R629= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs570697259; called by muse, mutect2, varscan2
- CSPG4 | c.1959G>A p.T653= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs147831235; called by muse, varscan2
- DTX1 | c.648C>T p.N216= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- FCRL1 | c.219C>T p.I73= | Silent (SNP) | VAF 182/512 reads (36%) | catalogued as rs763185136, COSV100839709; called by muse, mutect2, varscan2
- MDM4 | c.1101G>A p.S367= | Silent (SNP) | VAF 170/416 reads (41%) | catalogued as rs149259264; called by muse, mutect2, varscan2
- P2RX5 | c.1224C>T p.N408= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as rs201152395, COSV99835861; called by muse, mutect2, varscan2
- ZNF445 | c.3036A>G p.G1012= | Silent (SNP) | VAF 121/387 reads (31%) | called by muse, mutect2, varscan2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 90/252 reads (36%) | catalogued as rs147863190; called by muse, mutect2, varscan2
- CNOT3 | c.2037+215G>A | Intron (SNP) | VAF 56/133 reads (42%) | catalogued as rs371581098; called by muse, mutect2, varscan2
- SNORD52 | chr6:31837351 T>C | 3'Flank (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
